Somatic mutation profile of tumor specimen TCGA-KO-8407-01A (aliquot TCGA-KO-8407-01A-11D-2310-10) from TCGA case TCGA-KO-8407, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 42.2 years (15,407 days).
Specimen TCGA-KO-8407-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a60bc39a-c906-4760-886a-fda290c425dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KO-8407-11A (Solid Tissue Normal), aliquot TCGA-KO-8407-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86de1a19-ddb9-4cc1-b577-91320b0d2446

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Nonsense Mutation 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASTE1 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.187); catalogued as rs1385436786; called by muse, mutect2
- BPTF | c.5669G>A p.G1890D | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58848354; called by muse, mutect2
- CCNL1 | c.1328A>G p.H443R | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.26); catalogued as rs747466174; called by muse, mutect2, varscan2
- COL12A1 | c.5664G>T p.L1888= | Splice Region (SNP) | VAF 8/85 reads (9%) | catalogued as COSV100485188; called by muse, mutect2, varscan2
- COL5A3 | c.4421G>A p.R1474H | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs370182126; called by muse, varscan2
- KAT7 | c.938C>A p.A313E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99371551; called by muse, mutect2
- LRRC6 | c.21T>A p.D7E | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV99137678; called by muse, mutect2
- MYRIP | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as rs142520074; called by muse, mutect2, varscan2
- TAS1R3 | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as rs752614857; called by muse, mutect2, varscan2
- ZAN | c.7769G>A p.R2590H | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376796357; called by muse, mutect2
- C2orf49 | c.260C>A p.T87N | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- DNAH5 | c.13332G>A p.W4444* | Nonsense Mutation (SNP) | VAF 13/203 reads (6%) | called by muse, mutect2
- NCAPG2 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.012); called by muse, varscan2
- QSER1 | c.1634A>T p.Y545F (on ENST00000399302; = p.Y674F on NM_001076786.3) | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- RBX1 | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- TMEM31 | c.18G>C p.K6N | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- VILL | c.1026G>T p.Q342H | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- LILRA1 | c.1023C>T p.N341= | Silent (SNP) | VAF 13/151 reads (9%) | catalogued as rs746950244, COSV99251672; called by muse, mutect2
- PCDHA8 | c.1452G>A p.A484= | Silent (SNP) | VAF 29/160 reads (18%) | catalogued as COSV100969429, COSV65324193; called by muse, mutect2, varscan2
- SPG11 | c.4767C>T p.V1589= | Silent (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- WIPI1 | c.1266T>C p.C422= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- LRRC37B | chr17:32021121 C>G | 5'Flank (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
